Surgical pathology report (de-identified scan), TCGA case TCGA-94-7943, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Emory, specimen TCGA-94-7943-01A (Primary Tumor).

[page 1 of 4]
[REDACTED] Confidential Document
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [REDACTED] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date: [REDACTED]
Document Status: Auth (Verified)
Document Title: Histology
Encounter info: [REDACTED]

* Final Report *

APRPT (Verified)

Patient Name: [REDACTED] Acc #: [REDACTED]
MRN: [REDACTED] DOB: [REDACTED]
Location: [REDACTED] Gender: M
Client: [REDACTED] Collected: [REDACTED]
Submitting Phys: [REDACTED] Received: [REDACTED]
Reported: [REDACTED]

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. LUNG, LEFT, LINGULA AND MEDIAL SEGMENT LEFT LOWER LOBE, WEDGE BIOPSY AND SEGEMENTECTOMY, A1FS:

- POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 2.4 X 1.9 X 1.4 CM.
- VISCERAL PLEURAL INVASION IDENTIFIED.
- ANGIOLYMPHATIC INVASION IDENTIFIED.
- TUMOR IS LESS THAN 1MM FROM PARENCHYMAL RESECTION MARGIN.
- FIBROUS ADHESIONS.
- SEE COMMENT AND STAGING SUMMARY.

Printed by: [REDACTED]
Printed on: [REDACTED]

[page 2 of 4]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [REDACTED] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Comment

Elastic stains were evaluated to demonstrate visceral pleural invasion.

Synoptic Worksheet

A. Lingula and medial segment left lower lobe:

Specimen:	Lung
Procedure:	Other: wedge biopsy and segmentectomy
Specimen Integrity:	Disrupted
Specimen Laterality:	Left
Tumor Site:	Other: lingula and medial segment left lower lobe
Tumor Focality:	Unifocal
Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G3: Poorly differentiated
Tumor Size:	Greatest dimension: 2.4 cm Additional dimension: 1.9 cm Additional dimension: 1.4 cm
Visceral Pleura Invasion:	Present
Tumor Extension:	Not applicable
Bronchial Margin:	Involvement by invasive carcinoma not applicable Involvement by squamous cell carcinoma in situ (CIS) not applicable
Vascular Margin:	Not applicable
Parenchymal Margin:	Uninvolved by invasive carcinoma
Parietal Pleural Margin:	Not applicable
Chest Wall Margin:	Not applicable
Other Attached Tissue Margin:	Not applicable
All Margins Uninvolved By Invasive Carcinoma:	Distance of invasive carcinoma from closest margin: 1 mm Margin closest to invasive carcinoma: parenchymal
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Present
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT1b: Tumor greater than 2 cm, but 3 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus)
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assessed Involved nodal station(s): none

[page 3 of 4]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [REDACTED] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Distant Metastasis (pM): Not applicable

Clinical History

Left VATS with wedge resection, excision and biopsy.

Specimen(s) Received

A: Lingula and medial segment left lower lobe

Gross Description

Specimen A is received fresh in a container labeled with the patient's name and medical record number and as "wedge excision." The specimen consists of a two segments of lung adhered together measuring in total 6.0 x 5.5 x 2.2 cm and weighing 23.9 grams. Multiple staple lines are present in the specimen. Within the lung parenchyma is a solid mass with infiltrative borders measuring 2.4 x 1.9 x 1.4 cm. This mass abuts the parenchymal resection margin following staple line removal and appears to focally abut the overlying pleura. The pleura overlying the mass is disrupted prior to receipt in pathology. No additional masses are identified and the remaining lung parenchyma appears unremarkable. The pleura overlying the mass is inked green; the parenchymal resection margins are inked blue. A touch preparation of the nodule is performed. A portion of the nodule is submitted for frozen section diagnosis in cassette "A1FS." Tissue is submitted for [REDACTED] Representative sections are submitted as stated below. [REDACTED]

Cassette Summary:

A1FS:	Representative nodule
A2:	Mass overlying pleura and parenchymal resection margin
A3,4:	Mass and surrounding lung
A5:	Representative uninvolved lung

[REDACTED]

Intraoperative Consult Diagnosis

A1FS: LEFT LOWER LOBE LUNG WEDGE NODULE (FROZEN SECTION): NON SMALL CELL CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by [REDACTED]

[REDACTED]

Microscopic Description

Microscopic examination performed.

Printed by:
Printed on:

Page 3 of 4
(Continued)

[page 4 of 4]
[REDACTED]

Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [REDACTED] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

[REDACTED]

* Final Report *

[REDACTED]

Printed by:
Printed on:

[REDACTED]

Page 4 of 4
(End of Report)

Source: NCI Genomic Data Commons file 3dfd04a7-54ec-4325-8327-3e58b4e439fe (TCGA-94-7943.45EC950B-C7D1-421E-A6A7-79ADB212C169.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).